Gene-level copy-number profile of tumor specimen TCGA-CV-5430-01A from TCGA case TCGA-CV-5430, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 61.8 years (22,577 days).
Specimen TCGA-CV-5430-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.848d8d61-942d-41d4-a31b-654d9da79b6c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-5430-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ee21bd78-5afc-42f4-b011-fe80f01c6792

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 470; copy number 2: 11,956; copy number 3: 19,909; copy number 4: 18,343; copy number 5: 2,762; copy number 6: 2,681; copy number 7: 769; copy number 8: 1,633; copy number 9: 569; copy number 10: 121; copy number 11: 306; copy number 13: 7; copy number 14: 65; copy number 17: 82; copy number 18: 19; copy number 19: 1; copy number 23: 32; copy number 24: 27; copy number 32: 25; copy number 36: 16; copy number 47: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-5430-01A-02D-1682-01): tumor purity 0.57, ploidy 3.55, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,929,457–22,128,103, 9 genes (within-gene range 0–2): ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,498 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:93,843,764–115,147,288, 300 genes, copy number 9–11 (within-gene range 6–11) (broad region; genes not listed).
- chr4:70,902,326–76,421,868, 96 genes, copy number 8–9 (within-gene range 4–9) (broad region; genes not listed).
- chr8:35,862,123–43,674,591, 188 genes, copy number 9–23 (broad region; genes not listed).
- chr8:49,330,210–145,066,685, 1,470 genes, copy number 7–8 (broad region; genes not listed).
- chr11:69,641,156–70,436,584, 27 genes, copy number 9–18: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,604,859, 2 genes, copy number 18: AP001271.1, AP001271.2.
- chr11:135,061,781–135,075,908, 1 gene, copy number 7: LINC02684.
- chr12:66,767–11,171,608, 418 genes, copy number 9–14 (within-gene range 2–14) (broad region; genes not listed).
- chr12:15,911,302–21,604,847, 70 genes, copy number 8–24 (within-gene range 2–24) (broad region; genes not listed).
- chr12:22,625,075–28,978,685, 107 genes, copy number 8 (broad region; genes not listed).
- chr12:61,231,159–67,670,919, 132 genes, copy number 7–19 (broad region; genes not listed).
- chr14:19,975,444–44,386,064, 645 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).
- chr20:11,234,170–13,996,443, 31 genes, copy number 7–36: AL049649.1, RPS11P1, AL109837.2, AL109837.3, AL109837.1, PGAM3P, AL161938.1, LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1, AL109838.1, AL136460.1, PA2G4P2, LINC01722, AL078623.1, AL133331.1, LINC01723, SPTLC3, AL109983.1, ISM1, ISM1-AS1, AL050320.1, AL121782.1, TASP1, GAPDHP2, ESF1, NDUFAF5, SEL1L2, RNU6-278P.
- chr20:14,003,508–14,935,363, 11 genes, copy number 13–36: RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2, MACROD2-AS1, AL138808.1.

Autosomal genes at a single copy (total copy number 1): 184. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
